Somatic mutation profile of tumor specimen 1105248 (aliquot 7316UP-334-1105248) from CPTAC case C219555, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105248: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c48e2396-2e97-4f49-a832-cc9e12121561.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105285 (Blood Derived Normal), aliquot 7316UP-334-1105285; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65aa4485-b0b2-4e25-90ca-257f5096dff2

The open-access MAF lists 75 somatic variants for this specimen: 51 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 14, Intron 5, Nonsense Mutation 2, 5'UTR 2, 3'Flank 1, Splice Site 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 1000/4451 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KDR | c.3094C>T p.R1032* | Nonsense Mutation (SNP) | VAF 35/312 reads (11%) | hotspot (GDC flag); catalogued as rs767542615, COSV55758800; called by muse, mutect2, varscan2
- ABCA2 | c.1568G>C p.W523S (on ENST00000614293; = p.W493S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55802768; called by muse, mutect2
- ALOX5 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV65551322; called by muse, mutect2, varscan2
- CDH2 | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs199977445; called by muse, mutect2
- COL6A3 | c.5179C>T p.R1727W | Missense Mutation (SNP) | VAF 125/430 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs143074017; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- EPPK1 | c.6652C>T p.R2218C | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101599862; called by muse, mutect2, varscan2
- FGD5 | c.3781C>T p.R1261C | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs867308143; called by muse, mutect2, varscan2
- FLT4 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 63/487 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs756924526, COSV56100948; called by muse, mutect2, varscan2
- GLUD2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs200880803, COSV60151559, COSV60152177; called by muse, mutect2, varscan2
- KCNA4 | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761722050; called by muse, mutect2, varscan2
- KCNG2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs769581960, COSV60267267; called by muse, mutect2, varscan2
- KIF2C | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs201647887; called by muse, mutect2, varscan2
- MAP3K21 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV64042498; called by muse, mutect2, varscan2
- MUC16 | c.8645C>T p.T2882I | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs199712362; called by muse, mutect2
- PDILT | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs199754421, COSV56700754; called by muse, mutect2, varscan2
- POLN | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs777556943; called by muse, mutect2
- RFPL1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs150980053; called by muse, mutect2, varscan2
- ROBO4 | c.1324G>C p.A442P | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs774752196; called by muse, mutect2, varscan2
- SLFN13 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs768773834; called by muse, mutect2, varscan2
- SLFN13 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.285); catalogued as rs148604980; called by muse, mutect2
- ST8SIA2 | c.810C>A p.Y270* | Nonsense Mutation (SNP) | VAF 80/332 reads (24%) | catalogued as rs1375310199, COSV51571832; called by muse, mutect2, varscan2
- USH1G | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58881452; called by muse, mutect2, varscan2
- USP43 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs927663097; called by muse, mutect2
- ZNF202 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1169707380; called by muse, mutect2, varscan2
- ADAM32 | c.1795G>A p.G599S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ADGRD2 | c.1184T>C p.L395P | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- ANO3 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CHD1L | c.2657A>G p.Q886R | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.132); called by muse, mutect2
- DNAH11 | c.10970T>A p.L3657H | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DSP | c.8119A>T p.M2707L | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EIF4G2 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- HERC2P3 | n.1061-2A>T | Splice Site (SNP) | VAF 102/948 reads (11%) | called by muse, mutect2, varscan2
- IL3RA | c.995A>T p.Q332L | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- INSRR | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KHSRP | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LRRIQ3 | c.1520A>G p.E507G | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAGEB3 | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MUC16 | c.32816C>A p.T10939N | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2V1 | c.239C>A p.P80Q | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR51E1 | c.692T>C p.L231S | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- OXT | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 51/372 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PATL1 | c.1589A>G p.Y530C | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PCSK1N | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- SEC62 | c.570C>G p.D190E | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.429); called by muse, mutect2
- SPHK2 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 64/387 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAT4 | c.1847A>G p.E616G | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.266); called by mutect2, varscan2
- TMEM30A | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- WDR41 | c.477C>A p.N159K | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); called by muse, mutect2
- ZNF449 | c.1523T>C p.M508T | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.242); called by muse, varscan2
- ZNF800 | c.1868G>A p.C623Y | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF16 | c.351C>T p.A117= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as rs527744298; called by muse, mutect2, varscan2
- CNTNAP3B | c.2070G>C p.P690= | Silent (SNP) | VAF 34/449 reads (8%) | called by muse, mutect2
- FOSL2 | c.705G>A p.S235= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as rs199702734; called by muse, mutect2, varscan2
- GALNT17 | c.714C>T p.T238= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs758291046, COSV61146047; called by muse, mutect2, varscan2
- GPAT3 | c.285C>T p.D95= | Silent (SNP) | VAF 56/239 reads (23%) | catalogued as rs770258933, COSV52358359; called by muse, mutect2, varscan2
- GPD2 | c.12A>G p.Q4= | Silent (SNP) | VAF 64/242 reads (26%) | called by muse, mutect2, varscan2
- IL17A | c.303C>T p.N101= | Silent (SNP) | VAF 47/327 reads (14%) | catalogued as rs767532310; called by muse, mutect2, varscan2
- KCNH7 | c.627C>T p.S209= | Silent (SNP) | VAF 35/304 reads (12%) | catalogued as COSV59783341; called by muse, mutect2, varscan2
- LMBR1 | c.174G>A p.R58= | Silent (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- MC2R | c.324C>G p.S108= | Silent (SNP) | VAF 122/541 reads (23%) | called by muse, varscan2
- PTH1R | c.90C>T p.D30= | Silent (SNP) | VAF 102/396 reads (26%) | catalogued as rs781370785; called by muse, mutect2, varscan2
- SCN3A | c.5130C>T p.G1710= | Silent (SNP) | VAF 42/567 reads (7%) | called by muse, mutect2
- SETBP1 | c.147G>A p.P49= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as rs775091518, COSV56330089, COSV56336218; called by muse, mutect2, varscan2
- ZSCAN12 | c.288C>T p.T96= | Silent (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- AC244197.3 | c.*21C>G | 3'UTR (SNP) | VAF 70/156 reads (45%) | catalogued as COSV100558192; called by muse, mutect2, varscan2
- AK2 | c.94-2746G>A | Intron (SNP) | VAF 97/494 reads (20%) | called by muse, mutect2, varscan2
- CHMP5 | c.-13G>C | 5'UTR (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- CYB5RL | chr1:54171196 C>T | 3'Flank (SNP) | VAF 79/360 reads (22%) | catalogued as rs564385397, COSV55276747; called by muse, mutect2, varscan2
- EPPIN-WFDC6 | c.522+416C>A | Intron (SNP) | VAF 22/266 reads (8%) | called by muse, mutect2
- FLYWCH1 | c.1514-277G>A | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs1038542024; called by muse, mutect2, varscan2
- GGTLC2 | chr22:22642894 G>A | 5'Flank (SNP) | VAF 171/607 reads (28%) | called by muse, mutect2, varscan2
- TGM6 | c.-66G>A | 5'UTR (SNP) | VAF 97/303 reads (32%) | catalogued as rs764830062; called by muse, mutect2, varscan2
- TTN | c.30475+13G>C | Intron (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- UTY | c.152+25G>A | Intron (SNP) | VAF 89/160 reads (56%) | catalogued as rs750427743; called by muse, mutect2, varscan2
